Somatic mutation profile of tumor specimen TCGA-14-0736-01A (aliquot TCGA-14-0736-01A-01D-2280-08) from TCGA case TCGA-14-0736, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.9 years (18,219 days).
Specimen TCGA-14-0736-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbdbef06-eb57-41d4-bae0-42c2979a812f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0736-10C (Blood Derived Normal), aliquot TCGA-14-0736-10C-01D-2280-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/910c26fb-e184-4cce-b956-061e3ceeec92

The open-access MAF lists 65 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Nonsense Mutation 6, Splice Site 2, Splice Region 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSL | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs122460152, CM950099, COSV66964820; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.492+2del p.X164_splice | Splice Site (DEL) | VAF 7/36 reads (19%) | catalogued as rs1060500124, CD115958, CS982333, COSV64288576, COSV64288590; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ACVRL1 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101187896; called by muse, mutect2, varscan2
- APOB | c.851A>T p.Q284L | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99265921; called by muse, mutect2
- BAZ2B | c.5149G>C p.G1717R | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100600695, COSV100601057; called by muse, mutect2
- BPIFB2 | c.554A>T p.N185I | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99401373; called by muse, mutect2, varscan2
- BPNT1 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as COSV100435688; called by muse, mutect2, varscan2
- CALD1 | c.216C>T p.N72= | Splice Region (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100724202; called by muse, mutect2, varscan2
- CASP2 | c.1164G>C p.E388D | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100130987; called by muse, mutect2
- CDIP1 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99566527; called by muse, mutect2, varscan2
- CHST8 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.603); catalogued as COSV52861724, COSV99381045; called by muse, mutect2, varscan2
- CPA6 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52733115; called by muse, mutect2, varscan2
- CTCF | c.1623C>A p.H541Q | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99865228; called by muse, mutect2, varscan2
- DPP10 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370122794; called by muse, mutect2, varscan2
- ENTPD4 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 75/145 reads (52%) | catalogued as COSV62268801; called by muse, mutect2, varscan2
- FCRL3 | c.1520T>C p.L507P | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100943167; called by muse, mutect2, varscan2
- FHOD3 | c.3434C>T p.S1145L (on ENST00000359247 / NM_001281739.3; = p.S1162L on NM_025135.5) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs756604100, COSV99940946; called by muse, mutect2, varscan2
- FLG | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 155/508 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100911522, COSV64241780; called by muse, mutect2, varscan2
- GAS6 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 11/95 reads (12%) | catalogued as rs555163572, COSV100581463; called by muse, mutect2, varscan2
- GDAP1L1 | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV100697553; called by muse, mutect2, varscan2
- GRB7 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760987834, COSV100485472; called by muse, mutect2, varscan2
- GUCA1B | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100027723; called by muse, mutect2, varscan2
- HERC2 | c.11911G>A p.A3971T | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as rs778293898, COSV99873257; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.370G>C p.G124R | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99860833; called by muse, mutect2, varscan2
- KDM3B | c.3060G>A p.W1020* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100069500; called by muse, varscan2
- KRT15 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1336068521, COSV54179879; called by muse, mutect2, varscan2
- KRT6A | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs754716072, COSV58104134; called by muse, mutect2
- LGALS3BP | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370418817; called by muse, mutect2, varscan2
- MAML1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV99483158; called by muse, mutect2, varscan2
- METTL22 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV99371722; called by muse, mutect2, varscan2
- MUC17 | c.8398A>T p.M2800L | Missense Mutation (SNP) | VAF 34/555 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.067); catalogued as COSV100073602; called by muse, mutect2
- MYH1 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | catalogued as rs750331285, COSV56844274, COSV56856511; called by muse, mutect2, varscan2
- MYO7A | c.4976G>A p.R1659H | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs748007093, COSV101289106, COSV101289115; called by muse, mutect2, varscan2
- MYOCD | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480273905, COSV100590200; called by muse, mutect2, varscan2
- NDRG1 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs199995009, COSV100105957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OPRK1 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as rs745533525, COSV55569565; called by muse, mutect2, varscan2
- OR2V2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100080096; called by muse, mutect2, varscan2
- PCGF3 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100745261; called by muse, mutect2
- PRDM1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as rs775868156, COSV100958741; called by muse, mutect2, varscan2
- RBM47 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs781033383, COSV55937302, COSV99921054; called by muse, mutect2, varscan2
- SALL4 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs765004478, COSV99409387; called by muse, mutect2, varscan2
- SENP1 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99136966; called by muse, mutect2, varscan2
- SLC5A7 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99886754; called by muse, mutect2, varscan2
- SPTA1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs772799574, COSV63749744, COSV63759526; called by muse, mutect2, varscan2
- SUFU | c.454+1G>T p.X152_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100883019, COSV104425316; called by muse, mutect2, varscan2
- SV2C | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758111862, COSV100456087; called by muse, mutect2, varscan2
- TRIM26 | c.903G>C p.Q301H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV101443936; called by muse, mutect2
- TRPC1 | c.2325A>G p.I775M (on ENST00000476941 / NM_001251845.2; = p.I741M on NM_003304.4) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs762854141, COSV99858663; called by muse, mutect2, varscan2
- UNC13A | c.3061C>T p.R1021W | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1338203040, COSV99408163; called by muse, mutect2
- YTHDF2 | c.1579A>T p.R527W | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100863779; called by muse, mutect2
- DEPDC5 | c.378del p.Y127Ifs*51 | Frame Shift Del (DEL) | VAF 70/248 reads (28%) | called by mutect2, pindel, varscan2
- ACTRT1 | c.309A>G p.Q103= | Silent (SNP) | VAF 89/274 reads (32%) | catalogued as COSV100947574; called by muse, mutect2, varscan2
- CFAP57 | c.720C>T p.T240= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as COSV100993953, COSV65264226; called by muse, mutect2, varscan2
- DIDO1 | c.2205T>C p.P735= | Silent (SNP) | VAF 31/198 reads (16%) | catalogued as rs1314150072, COSV99825682; called by muse, mutect2, varscan2
- ETFBKMT | c.486A>G p.R162= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1030470545, COSV99861512; called by muse, varscan2
- HOXA7 | c.144C>G p.A48= | Silent (SNP) | VAF 14/347 reads (4%) | catalogued as rs1406773647, COSV99636493; called by muse, mutect2
- LRP2 | c.3606C>T p.G1202= | Silent (SNP) | VAF 105/247 reads (43%) | catalogued as rs759833611, COSV55542645; called by muse, mutect2, varscan2
- MUSK | c.1287G>A p.L429= | Silent (SNP) | VAF 64/124 reads (52%) | catalogued as COSV99504106; called by muse, mutect2, varscan2
- NDST4 | c.2229A>G p.V743= | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as rs746838434, COSV52127157, COSV99996666; called by muse, mutect2, varscan2
- OR2T1 | c.655C>A p.R219= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100822302, COSV63542612; called by muse, mutect2, varscan2
- PCNX1 | c.1062A>C p.T354= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV99455814; called by muse, mutect2, varscan2
- SYT12 | c.1044G>T p.P348= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV101210875; called by muse, mutect2, varscan2
- TEX15 | c.7929A>G p.P2643= (on ENST00000256246; = p.P3026= on NM_001350162.2) | Silent (SNP) | VAF 55/100 reads (55%) | catalogued as rs981460790, COSV99821273; called by muse, mutect2, varscan2
- ZMYND8 | c.2274G>A p.P758= (on ENST00000311275 / NM_001363741.2; = p.P778= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/180 reads (19%) | catalogued as rs770713974, COSV99520560; called by muse, mutect2, varscan2
- URB1 | c.664+1257T>A | Intron (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100784061; called by muse, mutect2, varscan2
